Somatic mutation profile of tumor specimen ALCH-AEF2-TTP1-A (aliquot ALCH-AEF2-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AEF2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 63.9 years (23,356 days).
Specimen ALCH-AEF2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5240acb-a5ee-4eb4-b715-511ef48e10f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEF2-NB1-A (Blood Derived Normal), aliquot ALCH-AEF2-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1da58fb-b121-424d-9584-3b151dab7f3c

The open-access MAF lists 29 somatic variants for this specimen: 18 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Nonsense Mutation 2, 3'Flank 1, RNA 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V0A2 | c.908A>G p.K303R | Missense Mutation (SNP) | VAF 42/908 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57750676; called by muse, mutect2
- CENPF | c.4643G>T p.G1548V | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs928129239, COSV65273412; called by muse, mutect2
- PTX3 | c.134C>A p.T45K | Missense Mutation (SNP) | VAF 32/783 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as rs1241223044; called by muse, mutect2
- SEPTIN12 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs200096858; called by muse, mutect2
- TPO | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 32/772 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV61095286, COSV61099964, COSV61110474; called by muse, mutect2
- ZFHX4 | c.8697C>A p.S2899R | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99255177; called by muse, mutect2
- ALG12 | c.1226A>G p.N409S | Missense Mutation (SNP) | VAF 32/1182 reads (3%) | PolyPhen benign (0.346); called by muse, mutect2
- CDH8 | c.1480C>A p.P494T | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP2A13 | c.707A>T p.Q236L | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2
- ITGA1 | c.3426A>C p.L1142F | Missense Mutation (SNP) | VAF 18/512 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2
- ITGB1BP2 | c.742A>T p.S248C | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- KCNH8 | c.2887C>A p.P963T | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.145); called by muse, mutect2
- LDLRAD4 | c.404del p.P135Rfs*71 | Frame Shift Del (DEL) | VAF 4/85 reads (5%) | called by mutect2, pindel*
- MCF2 | c.1798A>T p.T600S | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PCDH11X | c.3274G>T p.E1092* | Nonsense Mutation (SNP) | VAF 45/687 reads (7%) | called by muse, mutect2
- PCDHB4 | c.1907A>T p.K636M | Missense Mutation (SNP) | VAF 40/1044 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- PRDM14 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 14/298 reads (5%) | called by muse, mutect2
- WIF1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2
- AKAP6 | c.3819T>C p.Y1273= | Silent (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- GBA | c.255G>A p.G85= | Silent (SNP) | VAF 16/274 reads (6%) | called by muse, mutect2
- IL1R2 | c.1164T>G p.P388= | Silent (SNP) | VAF 11/198 reads (6%) | called by muse, mutect2
- MTUS1 | c.1596C>T p.P532= | Silent (SNP) | VAF 11/344 reads (3%) | called by muse, mutect2
- OTOF | c.1704G>T p.R568= | Silent (SNP) | VAF 25/806 reads (3%) | called by muse, mutect2
- PCYOX1L | c.760C>T p.L254= | Silent (SNP) | VAF 23/451 reads (5%) | called by muse, mutect2
- PDZD4 | c.1482G>T p.R494= | Silent (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- SEC16B | c.1533A>G p.P511= | Silent (SNP) | VAF 30/682 reads (4%) | called by muse, mutect2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as rs73150876; called by mutect2, varscan2
- CES1P1 | n.623G>T | RNA (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- TRIQK | chr8:92884864 T>C | 3'Flank (SNP) | VAF 17/465 reads (4%) | called by muse, mutect2
